Somatic mutation profile of tumor specimen TCGA-HD-7753-01A (aliquot TCGA-HD-7753-01A-11D-2078-08) from TCGA case TCGA-HD-7753, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-HD-7753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2de6e66e-a3cd-4b5f-9234-7cfea820125c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-7753-10A (Blood Derived Normal), aliquot TCGA-HD-7753-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c48cbb26-5971-4398-bc6b-a00376756dba

The open-access MAF lists 107 somatic variants for this specimen: 88 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 16, Nonsense Mutation 7, Frame Shift Del 5, Frame Shift Ins 4, 5'UTR 1, 3'Flank 1, Splice Site 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs397514628, CM1211999, COSV100938153, COSV65040077, COSV65043006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.820_822dup p.V274dup | In Frame Ins (INS) | VAF 17/41 reads (41%) | hotspot (GDC flag); catalogued as COSV53572170; called by mutect2, pindel
- ADAMTS10 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs782547236, COSV54353135, COSV99547397; called by muse, mutect2, varscan2
- ADGRG2 | c.1897T>C p.Y633H (on ENST00000379869 / NM_001079858.3; = p.Y630H on NM_005756.4) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs748480298, COSV100492651; called by muse, mutect2, varscan2
- ARMC9 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100590038; called by mutect2, varscan2
- B3GNT2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV100114300; called by muse, mutect2, varscan2
- B4GAT1 | c.1212G>C p.L404F | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100240377; called by muse, mutect2, varscan2
- CDH10 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as COSV52589304, COSV52595236; called by muse, mutect2, varscan2
- CHD9 | c.8266A>G p.R2756G (on ENST00000398510 / NM_001382353.1; = p.R2740G on NM_025134.7) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV99529716; called by muse, mutect2, varscan2
- CNTNAP2 | c.1010T>G p.M337R | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100671990, COSV62261190; called by muse, mutect2, varscan2
- COQ6 | c.1155T>A p.D385E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474160; called by muse, mutect2, varscan2
- CSMD1 | c.8689A>G p.T2897A (on ENST00000520002; = p.T2896A on NM_033225.6) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV100153375; called by muse, mutect2, varscan2
- CYP7A1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100052629; called by muse, mutect2, varscan2
- DCC | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100498089; called by muse, mutect2, varscan2
- DDX60 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67095925; called by muse, mutect2, varscan2
- DNAH3 | c.3506T>C p.L1169P | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV99770431; called by muse, mutect2, varscan2
- DPP6 | c.1228C>G p.L410V (on ENST00000377770 / NM_001364500.2; = p.L348V on NM_001936.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.159); catalogued as COSV100127976; called by muse, mutect2
- ERBB3 | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99917793; called by muse, mutect2, varscan2
- FAM53B | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99785051; called by muse, mutect2
- FAM83B | c.954C>G p.S318R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100174461, COSV100174988; called by muse, mutect2, varscan2
- GCN1 | c.4934T>G p.L1645R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325936; called by muse, mutect2, varscan2
- IQCH | c.2932A>G p.I978V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100246317; called by muse, mutect2, varscan2
- IRX1 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100116797; called by muse, mutect2, varscan2
- KDM4C | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs376253166; called by muse, mutect2, varscan2
- KIF27 | c.1090A>C p.K364Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV99926969, COSV99927277; called by muse, mutect2, varscan2
- KLKB1 | c.1726-1G>T p.X576_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | catalogued as COSV99250405; called by muse, mutect2, varscan2
- KNTC1 | c.5579A>G p.Y1860C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs930931941, COSV100338795; called by muse, mutect2, varscan2
- LRP1B | c.13752A>T p.E4584D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV101260537; called by muse, mutect2
- LRRC27 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747857537, COSV100689948; called by muse, mutect2, varscan2
- MED1 | c.4301C>T p.P1434L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100328145; called by muse, mutect2, varscan2
- MED13L | c.4786A>G p.I1596V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99930095; called by muse, mutect2, varscan2
- MED25 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100457955; called by muse, mutect2, varscan2
- MID1 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV58199991; called by muse, mutect2, varscan2
- MTUS2 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as COSV101462356; called by muse, mutect2, varscan2
- OR2A2 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV68871805; called by muse, mutect2, varscan2
- OR2T3 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100613401; called by muse, mutect2, varscan2
- OR2T3 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100613403; called by muse, mutect2, varscan2
- OR2T34 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as COSV100170543; called by muse, mutect2, varscan2
- PARP12 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99694258; called by muse, mutect2, varscan2
- PCDH8 | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100132013; called by muse, mutect2
- PCDHA3 | c.1535C>A p.A512E | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PLCL2 | c.1764A>C p.E588D (on ENST00000615277 / NM_001144382.2; = p.E462D on NM_015184.5) | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV101196972; called by muse, mutect2, varscan2
- POMC | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as COSV99256979; called by muse, mutect2, varscan2
- PRDM9 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV99691210; called by muse, mutect2, varscan2
- PRKAA1 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as rs747116005, COSV99713411; called by muse, mutect2, varscan2
- PRRC2C | c.3089G>T p.R1030L (on ENST00000367742; = p.R1028L on NM_015172.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100145698; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.224); catalogued as COSV100842988, COSV100843125; called by muse, mutect2, varscan2
- RASGRP4 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.437); catalogued as COSV53039970; called by muse, mutect2, varscan2
- RIF1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99691214; called by muse, mutect2, varscan2
- RIT2 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760273264, COSV99951070; called by muse, mutect2, varscan2
- RTL9 | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 103/160 reads (64%) | catalogued as COSV101511788; called by muse, mutect2, varscan2
- SAMD8 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV101014179; called by muse, mutect2, varscan2
- SCMH1 | c.1214C>T p.A405V (on ENST00000326197 / NM_001031694.2; = p.A358V on NM_012236.4) | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100402161; called by muse, mutect2, varscan2
- SLC35F5 | c.1490T>A p.I497N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV99830261; called by muse, mutect2, varscan2
- SLCO3A1 | c.1471A>T p.I491F | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100575898; called by muse, mutect2, varscan2
- SLITRK5 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100281182; called by muse, mutect2, varscan2
- SORBS2 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); catalogued as COSV99512630; called by muse, mutect2, varscan2
- SPAG17 | c.2921A>G p.N974S | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100310480; called by muse, mutect2, varscan2
- SPART | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774657699, COSV100768853; called by muse, mutect2, varscan2
- SYT4 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.506); catalogued as COSV54900166, COSV99674357; called by muse, mutect2
- TANC2 | c.1961A>G p.Y654C | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs997966810, COSV101267664; called by muse, mutect2, varscan2
- TMEM117 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.828); catalogued as rs1565596464, COSV56900989, COSV99863638; called by muse, mutect2, varscan2
- TOM1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 39/141 reads (28%) | catalogued as rs1183858575, COSV101147086; called by muse, mutect2, varscan2
- TRHR | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 211/404 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100305097; called by muse, mutect2, varscan2
- TRPM7 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV100540302; called by muse, mutect2, varscan2
- TTC3 | c.5236C>T p.P1746S | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100696016; called by muse, mutect2, varscan2
- UPK1B | c.9A>T p.K3N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99953808; called by muse, mutect2, varscan2
- VPS13A | c.3199G>C p.D1067H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100652968, COSV100653478; called by muse, mutect2, varscan2
- VWA5A | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100827959; called by muse, mutect2, varscan2
- ZADH2 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100463560, COSV59268606; called by muse, mutect2, varscan2
- ZC3H4 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs968828882, COSV99452764; called by muse, mutect2, varscan2
- ZNF354C | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100203775; called by muse, mutect2, varscan2
- ZNF383 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100776794; called by muse, mutect2, varscan2
- ZNF404 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100182844; called by muse, mutect2, varscan2
- ZNF521 | c.465C>G p.F155L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100833334; called by muse, mutect2, varscan2
- ZNF611 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV100160584; called by muse, mutect2, varscan2
- ZZEF1 | c.7540A>T p.I2514L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV101068059; called by muse, mutect2, varscan2
- AJUBA | c.970_976del p.R324Gfs*84 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- CAPN11 | c.1824_1837del p.G609Cfs*11 | Frame Shift Del (DEL) | VAF 54/272 reads (20%) | called by mutect2, pindel*, varscan2
- CD28 | c.367del p.L123* | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- CSMD3 | c.4107_4129del p.Q1369Hfs*15 (on ENST00000297405 / NM_001363185.1; = p.Q1265Hfs*15 on NM_052900.3) | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- HERC2 | c.7659dup p.R2554Tfs*3 | Frame Shift Ins (INS) | VAF 38/110 reads (35%) | called by mutect2, pindel, varscan2
- LGR4 | c.1736_1743dup p.V582* | Nonsense Mutation (INS) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- MYO18B | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDZD2 | c.8084_8085insAACA p.L2696Tfs*58 | Frame Shift Ins (INS) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- SLC49A3 | c.597dup p.T200Yfs*115 (on ENST00000404286 / NM_001294341.2; = p.T200Yfs*114 on NM_032219.4) | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- VASN | c.1503dup p.S502Ifs*4 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- VPS13D | c.9491_9492del p.S3164* | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- ABCA13 | c.7749A>G p.T2583= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs762302345, COSV101447193; called by muse, mutect2, varscan2
- CD163 | c.2403C>T p.H801= | Silent (SNP) | VAF 54/188 reads (29%) | catalogued as rs977803294, COSV63131083, COSV63135337; called by muse, mutect2, varscan2
- DAGLA | c.2931C>G p.A977= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV57198205, COSV99944712; called by muse, mutect2, varscan2
- DOCK7 | c.6417T>C p.D2139= (on ENST00000635253 / NM_001367561.1; = p.D2108= on NM_033407.3) | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99225892; called by muse, mutect2, varscan2
- FOLH1 | c.171T>C p.N57= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99923885; called by muse, mutect2, varscan2
- GALNT13 | c.1164C>T p.V388= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101224173; called by muse, mutect2, varscan2
- LRRC37B | c.2221C>T p.L741= | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as rs748993321, COSV100496524; called by muse, mutect2, varscan2
- MRC2 | c.3822G>T p.R1274= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100316740; called by muse, mutect2, varscan2
- MYO18B | c.2112C>A p.G704= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- OR2T34 | c.102C>A p.T34= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs745524809, COSV100170541, COSV60899543; called by muse, mutect2, varscan2
- ST8SIA2 | c.1113C>T p.C371= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs113311093, COSV51569217; called by muse, mutect2, varscan2
- TAGLN2 | c.87C>T p.I29= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57424178; called by muse, mutect2, varscan2
- TRAPPC11 | c.2991C>A p.I997= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV100592038, COSV58218039; called by muse, mutect2, varscan2
- UMODL1 | c.3651C>A p.L1217= (on ENST00000408910 / NM_001004416.2; = p.L1345= on NM_173568.3) | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101252705; called by muse, mutect2, varscan2
- ZNF286A | c.1311C>T p.P437= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV101224843; called by muse, mutect2, varscan2
- ZNF99 | c.1239T>C p.T413= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs757941521, COSV101233960; called by muse, mutect2, varscan2
- ACTL8 | c.-2C>T | 5'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100958791; called by muse, mutect2
- EMC3-AS1 | chr3:10007488 C>G | 3'Flank (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- MIR527 | n.62C>G | RNA (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
